Somatic mutation profile of tumor specimen 97cc4d46-cf80-41f1-b99c-bc4829 (aliquot 97cc4d46-cf80-41f1-b99c-bc4829_D6_1) from CPTAC case 11BR060, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 52.8 years (19,284 days).
Specimen 97cc4d46-cf80-41f1-b99c-bc4829: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54d6163c-3773-4890-90f4-79c1a97e1cbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 23d5da6f-7593-4652-8db6-07372e (Blood Derived Normal), aliquot 23d5da6f-7593-4652-8db6-07372e_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d7f4096-8455-451d-bfc9-eca0fd59aa8f

The open-access MAF lists 132 somatic variants for this specimen: 90 protein-altering or splice-affecting, 25 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 25, Nonsense Mutation 7, Intron 7, RNA 4, 5'UTR 3, Frame Shift Ins 3, Splice Region 2, Splice Site 1, In Frame Del 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 90/183 reads (49%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.6632G>A p.G2211E | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774503989, COSV67986938; called by muse, mutect2, varscan2
- AMER1 | c.3047C>T p.S1016F | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.451); catalogued as rs1230215835; called by muse, mutect2, varscan2
- AXIN2 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as rs1279069233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAP | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs774167522; called by muse, mutect2, varscan2
- CELSR2 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs1557733537; called by muse, mutect2, varscan2
- CNKSR2 | c.2185C>T p.R729* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as COSV54252247; called by muse, mutect2, varscan2
- COL19A1 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.122); catalogued as COSV59564643, COSV59580388; called by muse, mutect2, varscan2
- CSMD3 | c.2362C>G p.L788V (on ENST00000297405 / NM_001363185.1; = p.L684V on NM_052900.3) | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV52188167; called by muse, mutect2, varscan2
- DDX56 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770985431, COSV51838208; called by muse, mutect2, varscan2
- ETV7 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV60318277; called by muse, mutect2, varscan2
- GLIS3 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 49/393 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV100172996; called by muse, mutect2, varscan2
- GLMN | c.1454A>G p.D485G | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs779472104; called by muse, mutect2, varscan2
- GPR155 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 90/384 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs528682867, COSV55039349; called by muse, mutect2, varscan2
- HDHD3 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs747591014, COSV53056601; called by muse, mutect2, varscan2
- HIVEP3 | c.4711C>G p.L1571V | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV99911644; called by muse, mutect2
- LGI2 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV66122933; called by muse, mutect2
- LRRC66 | c.1223dup p.C409Vfs*20 | Frame Shift Ins (INS) | VAF 27/159 reads (17%) | catalogued as rs752924856; called by mutect2, varscan2
- MCM4 | c.1835C>G p.S612C | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100031813; called by muse, mutect2, varscan2
- MOV10L1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs760413650, COSV53171565; called by muse, mutect2, varscan2
- NEURL1 | c.1213G>C p.A405P | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.511); catalogued as rs201438416; called by muse, mutect2, varscan2
- NPAT | c.211A>T p.T71S | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV99586017; called by muse, mutect2, varscan2
- NUDT6 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.761); catalogued as rs1486683779; called by muse, mutect2, varscan2
- PELP1 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.051); catalogued as rs749038727, COSV52586391; called by muse, mutect2, varscan2
- RAD9B | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.828); catalogued as rs1247133704; called by muse, mutect2, varscan2
- SLC4A3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99812493; called by muse, mutect2, varscan2
- TENT4A | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV50099848; called by muse, mutect2, varscan2
- TOM1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 276/392 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs374115421; called by muse, mutect2, varscan2
- TUBA3C | c.1003A>G p.I335V | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs975947907; called by muse, mutect2, varscan2
- UNKL | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1442409606; called by muse, mutect2
- VAV1 | c.207C>T p.F69= | Splice Region (SNP) | VAF 34/91 reads (37%) | catalogued as rs780489736; called by muse, mutect2, varscan2
- XIRP2 | c.136G>T p.E46* (on ENST00000628543; = p.E221* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 28/153 reads (18%) | catalogued as COSV54700317, COSV99740132; called by muse, mutect2, varscan2
- XIRP2 | c.2170dup p.I724Nfs*5 (on ENST00000628543; = p.I899Nfs*5 on NM_152381.6) | Frame Shift Ins (INS) | VAF 77/302 reads (25%) | catalogued as rs773624352; called by mutect2, pindel, varscan2
- ZNF831 | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV64040522; called by muse, mutect2, varscan2
- APC2 | c.4043G>A p.G1348E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.505); called by muse, varscan2
- CBX6 | c.413A>T p.D138V | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCAR2 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 66/341 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCDC141 | c.722A>C p.Q241P | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CDH9 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 46/415 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK13 | c.3670C>G p.P1224A | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CEP112 | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); called by muse, varscan2
- CFAP65 | c.4496C>A p.T1499K | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CHAD | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- CLEC1A | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by mutect2, varscan2
- CNOT1 | c.918_919dup p.G307Vfs*33 | Frame Shift Ins (INS) | VAF 14/121 reads (12%) | called by mutect2, pindel, varscan2
- COL25A1 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRY2 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DENND2D | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLG5 | c.1574G>A p.W525* | Nonsense Mutation (SNP) | VAF 108/677 reads (16%) | called by muse, mutect2, varscan2
- EARS2 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- EPHX2 | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM83D | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, varscan2
- FMO4 | c.1531A>G p.M511V | Missense Mutation (SNP) | VAF 75/606 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXN2 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
- GMEB2 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- GREB1 | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRK3 | c.1552C>G p.Q518E | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2
- GTPBP1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPR | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IGHV3-16 | c.105del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 41/225 reads (18%) | called by mutect2, pindel, varscan2
- KRT1 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- L3MBTL4 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLH3 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 33/314 reads (11%) | called by muse, mutect2, varscan2
- MRM1 | c.393G>C p.W131C | Missense Mutation (SNP) | VAF 77/422 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.26468C>A p.S8823Y | Missense Mutation (SNP) | VAF 25/267 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.223); called by muse, mutect2
- NMNAT2 | c.321+1G>A p.X107_splice | Splice Site (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- NT5E | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 52/572 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- OGN | c.778A>T p.T260S | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.056); called by muse, mutect2
- PAF1 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- PCDHB4 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 136/593 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PCF11 | c.3679C>T p.Q1227* | Nonsense Mutation (SNP) | VAF 38/227 reads (17%) | called by muse, mutect2, varscan2
- PLA2G4A | c.293T>G p.M98R | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.449); called by muse, mutect2
- PLA2G4E | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- PTPRG | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- PYROXD1 | c.320_337del p.Y107_L112del | In Frame Del (DEL) | VAF 24/148 reads (16%) | called by mutect2, pindel, varscan2
- RAB3A | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB5C | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- RBM11 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBM12 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ROBO3 | c.2912G>A p.R971Q | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SARM1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 110/537 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- SCN3A | c.2707C>T p.L903F | Missense Mutation (SNP) | VAF 78/469 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAM2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- STYXL2 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TAF7L | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.88544G>C p.G29515A (on ENST00000591111; = p.G22091A on NM_003319.4) | Missense Mutation (SNP) | VAF 15/537 reads (3%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- UGGT1 | c.3811C>T p.L1271F | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VKORC1 | c.73T>A p.Y25N | Missense Mutation (SNP) | VAF 24/462 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WHAMM | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 125/422 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- XRN2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.079); called by muse, mutect2
- ADCK2 | c.312C>G p.G104= | Silent (SNP) | VAF 27/237 reads (11%) | called by muse, mutect2, varscan2
- ASPSCR1 | c.1362C>T p.L454= | Silent (SNP) | VAF 27/129 reads (21%) | called by muse, mutect2, varscan2
- ATP6V1H | c.693G>A p.L231= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV62218255; called by muse, mutect2, varscan2
- CASS4 | c.1926G>A p.K642= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as COSV100824854; called by muse, mutect2
- CCDC148 | c.399G>A p.L133= | Silent (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- CHAD | c.879G>A p.E293= | Silent (SNP) | VAF 38/248 reads (15%) | called by muse, mutect2
- GRM7 | c.1743C>T p.I581= | Silent (SNP) | VAF 18/266 reads (7%) | catalogued as rs375970414, COSV63151322; called by muse, mutect2
- HNRNPL | c.1518C>T p.F506= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs1205392438; called by muse, mutect2, varscan2
- KDM5B | c.1296G>A p.K432= | Silent (SNP) | VAF 48/169 reads (28%) | called by muse, mutect2, varscan2
- LRFN5 | c.30C>T p.L10= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV53243411; called by muse, mutect2, varscan2
- LTK | c.1653G>A p.S551= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs375203744, COSV99540644; called by muse, mutect2, varscan2
- MACO1 | c.39C>G p.R13= | Silent (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- MAGEA6 | c.120C>T p.S40= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as rs1556826006; called by muse, mutect2, varscan2
- MAGEC1 | c.987T>C p.T329= | Silent (SNP) | VAF 50/527 reads (9%) | called by muse, mutect2
- MOV10L1 | c.1575G>A p.L525= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- NALCN | c.3309C>T p.N1103= | Silent (SNP) | VAF 135/208 reads (65%) | catalogued as rs1035085564, COSV51969687; called by muse, mutect2, varscan2
- NKX6-2 | c.456C>T p.R152= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as rs760892833; called by mutect2, varscan2
- SIGLEC1 | c.132C>T p.S44= | Silent (SNP) | VAF 79/257 reads (31%) | called by muse, mutect2, varscan2
- SPTA1 | c.2625G>A p.K875= | Silent (SNP) | VAF 24/545 reads (4%) | catalogued as COSV100935039; called by muse, mutect2
- SRCAP | c.5592T>C p.A1864= | Silent (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- STAB2 | c.6339A>C p.G2113= | Silent (SNP) | VAF 22/236 reads (9%) | called by muse, mutect2
- TBC1D9B | c.504C>G p.R168= | Silent (SNP) | VAF 29/310 reads (9%) | catalogued as COSV62283485; called by muse, mutect2
- VN1R4 | c.147G>A p.L49= | Silent (SNP) | VAF 41/348 reads (12%) | called by muse, mutect2, varscan2
- VN1R5 | c.501C>T p.F167= | Silent (SNP) | VAF 96/484 reads (20%) | catalogued as rs773432464; called by muse, mutect2, varscan2
- ZNF34 | c.111C>T p.F37= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs200323832; called by muse, mutect2, varscan2
- CRACR2B | c.693+73G>A | Intron (SNP) | VAF 100/307 reads (33%) | catalogued as rs964863946; called by muse, mutect2, varscan2
- MORF4 | n.540C>T | RNA (SNP) | VAF 22/602 reads (4%) | called by muse, mutect2
- NHSL2 | chrX:72143455 G>T | 3'Flank (SNP) | VAF 42/215 reads (20%) | called by muse, mutect2, varscan2
- OSBPL2 | chr20:62233206 G>T | 5'Flank (SNP) | VAF 30/303 reads (10%) | called by muse, mutect2, varscan2
- PREP | c.1119+610G>A | Intron (SNP) | VAF 17/236 reads (7%) | catalogued as rs1348536332; called by muse, mutect2
- RSPH1 | c.-6G>A | 5'UTR (SNP) | VAF 19/178 reads (11%) | called by muse, mutect2, varscan2
- SLC25A46 | c.284-50A>G | Intron (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- SLC6A13 | c.202+15C>A | Intron (SNP) | VAF 30/390 reads (8%) | called by muse, mutect2
- SMG1P2 | n.1509G>A | RNA (SNP) | VAF 30/184 reads (16%) | called by muse, mutect2, varscan2
- STOM | c.-19C>G | 5'UTR (SNP) | VAF 17/177 reads (10%) | called by muse, mutect2
- STT3B | c.1327+102T>G | Intron (SNP) | VAF 32/157 reads (20%) | called by muse, mutect2, varscan2
- TEKT4 | c.499-568C>T | Intron (SNP) | VAF 35/127 reads (28%) | catalogued as rs112976342, COSV54622909; called by muse, mutect2, varscan2
- TG | c.7239+17709C>T | Intron (SNP) | VAF 121/202 reads (60%) | catalogued as rs545221868; called by muse, mutect2, varscan2
- WNT3A | c.-11C>G | 5'UTR (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- ZNF204P | n.881T>A | RNA (SNP) | VAF 110/242 reads (45%) | called by muse, mutect2, varscan2
- ZNF234 | c.*61A>C | 3'UTR (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- ZNF658B | n.2053G>A | RNA (SNP) | VAF 218/622 reads (35%) | called by mutect2, varscan2
